Surgical pathology report (de-identified scan), TCGA case TCGA-66-2771, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2771-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right upper lobe wedge

Clinical diagnosis and question

Suspected right bronchial carcinoma S2/6.

REPORT ON FINDINGS**Macroscopy**

- 1.) Right upper lobe wedge: inflated, fixed resected lung tissue measuring 9 x 5 cm at the base to 3.5 cm thick with a 13 cm long staple suture line and pleural margin. Visceral pleura fine reticulate pattern of blackish pigmentation. Pleura at pleural margin show a star-shaped retraction and partly whitish thickening in an area of about 2.5 cm. Below this is a focal pale brown tumor, max. 2.9 cm in size, with an arcuate demarcation, extending to the staple suture line. Surrounding parenchyma shows slight focal rarefaction with lacunae up to 0.4 cm in size.
- 2.) Inflated, fixed residual upper lobe of lung measuring 20.5 x 14 x 6.5 cm, central bronchus resection plane located 0.4 cm proximal to the bifurcation of B1. At the hilus is a 1.6 cm lesioned grayish-black node. At the dorsal margin runs a vertical 13 cm long staple suture line, at the staple suture line lateral visceral pleura is missing in an area of 4.5 x 1 cm. At the lower retracted margin of the pulmonary lobe a 14.5 cm long staple suture line, branching off this to the hilus a 4 cm long staple suture line, and in the digon of the staple suture line lateral visceral pleura is missing in an area of 2 x 2 cm. Otherwise, visceral pleura shows slightly patchy, in part vaguely reticulate blackish pigmentation, and in part turbid and cloudy in appearance. Parenchyma below the staple suture lines shows slight bleeding. Subsegmental branches of B2 and 3 ending in the region of the staple suture lines described. Rest of parenchyma, especially in the apical region in S1, is rarefied with the formation of lacunae up to 0.5 cm.
- 3.) Lobar LN (station 12) right upper lobe: two node parts with sparse surrounding tissue, 0.8 and 1.3 cm in size.
- 4.) Interlobar LN (station 11) right 1.2 cm node.
- 5.) Hilar LN (station 10) right: 2.2 cm fatty tissue with 2 node halves each 1 cm in size and a 0.5 cm piece of fatty tissue.
- 6.) Low paratracheal LN (station 4) right: 2 cm fatty tissue with 3 nodes or node parts between 0.7 and 1.3 cm in size.
- 7.) Paraesophageal LN (station 8): 0.7 cm node and a 0.5 cm flat piece of fatty tissue.
- 8.) Subcarinal LN (station 7): 1.5 cm lesioned node with surrounding tissue.

Examined:

- 1.) Rapid section remains, 2 sections of tumor with base marked green,
- 2.) 1 section from the area of the first-mentioned staple suture line (marked green, in the area of the missing visceral pleura marked orange), 1 section from the area of the second-mentioned staple suture line (identical color marking), 1 section S1 apical, bronchus and vascular resection margins (tangential) and hilar nodes,
- 3.), 4.), 6.) + 8.) All material,
- 5.) + 7.) nodes in each case,
- 13 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

[page 2 of 2]
Microscopy

Re 1.) Immediate intraoperative evaluation ([REDACTED]); large-cell solid carcinoma, PC possible.
Description of histological and cytological findings omitted for capacity reasons.

EVALUATION**Primary diagnosis/diagnoses:**

Peripheral bronchopulmonary, histologically very poorly differentiated or largely undifferentiated, large-cell squamous cell carcinoma of the right upper lobe of the lung. Tumor classification according to this picture pT2 pN1 V1 R0, stage IIB. C34.1 M8070/3, G4.

Secondary diagnosis/diagnoses:

Small tumor necroses and tumor-related inflammation with microabscess formations. Local chronic concomitant pleuritis. Marked emphysematous stromal remodeling of the lung parenchyma with formation of subpleural cysts. Small clusters of alveolar pigment macrophages. Lymph nodes with slight to moderate anthracotic pigment deposit and reactive macrophages and in some cases small foci of epithelioid cell reaction.

Remark/addendum:

The carcinoma shows focal invasion of the visceral pleura that is enlarged with connective tissue in the retracted area. A micrometastasis affects the hilus lymph node at the residual upper lobe, a somewhat larger lymph node metastasis is found in sample 3.) (maximum spreads in the section plane almost 3 mm). The carcinoma lies in the wedge resection registered under 1.) and extends here to the staple suture line. The subsequent residual upper lobe is tumor-free.

Source: NCI Genomic Data Commons file baed7723-1153-4b4c-8667-d943ed398b0e (TCGA-66-2771.E09C6C36-88A1-4F23-8611-241130866096.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).